Somatic mutation profile of tumor specimen TCGA-QT-A5XO-01A (aliquot TCGA-QT-A5XO-01A-11D-A35D-08) from TCGA case TCGA-QT-A5XO, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 63.4 years (23,154 days).
Specimen TCGA-QT-A5XO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de03af28-09a3-425b-a1f3-ceca1d50ece7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QT-A5XO-10A (Blood Derived Normal), aliquot TCGA-QT-A5XO-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06b91bf4-cd5e-4443-9b29-2da00dc60e89

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 14, Silent 6, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKFN1 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); catalogued as rs1555639432; called by muse, mutect2, varscan2
- EGLN1 | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs541542280; called by muse, mutect2, varscan2
- FMO3 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100882491; called by muse, mutect2, varscan2
- HFM1 | c.59A>G p.D20G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1382373708; called by muse, mutect2, varscan2
- PGR | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450222910, COSV54799232; called by muse, mutect2, varscan2
- SACS | c.11624G>T p.R3875L | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs863224916, CM138559, COSV66538706; called by muse, mutect2, varscan2
- SH3BP4 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1288428467; called by muse, mutect2, varscan2
- ADAM2 | c.1751G>T p.S584I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CACYBP | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- CSTL1 | c.52_70del p.L18Tfs*13 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- KCTD3 | c.1865A>G p.H622R | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD5 | c.2465C>G p.P822R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- MUC16 | c.4476G>A p.M1492I | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPEN | c.9026C>G p.A3009G | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TM2D1 | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.043); called by muse, mutect2
- ALKBH1 | c.57G>A p.G19= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs897451887; called by muse, mutect2, varscan2
- FLII | c.2583G>C p.G861= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1245579259; called by muse, mutect2, varscan2
- HSP90AA1 | c.387T>A p.S129= | Silent (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- OR10T2 | c.57C>T p.S19= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100555118; called by muse, mutect2, varscan2
- TBP | c.234G>A p.Q78= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs113440919, COSV57830415; called by muse, varscan2
- WDR64 | c.1110C>T p.A370= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs142859030; called by muse, mutect2, varscan2
